Gene-level copy-number profile of specimen HCM-SANG-0535-C20-85A-01D-A80T-32 from HCMI case HCM-SANG-0535-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0535-C20-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 67e0cf34-3052-4174-a5d6-dc67011f867b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0535-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/33fb1b76-f863-4b69-b24b-4f00b9496ac6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 392; copy number 1: 12,230; copy number 2: 42,360; copy number 3: 3,818; copy number 5: 117.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 117 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:43,831,942–51,225,575, 116 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr2:51,011,777–51,016,950, 1 gene, copy number 5: AC007682.1.

Autosomal genes at a single copy (total copy number 1): 9,766. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
